Somatic mutation profile of tumor specimen C3N-02339-02 (aliquot CPT0136640009) from CPTAC case C3N-02339, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 79.0 years (28,848 days).
Specimen C3N-02339-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38d34bb4-1ec3-4f49-98b8-d6ada769575e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02339-71 (Blood Derived Normal), aliquot CPT0136750002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/faef5bc3-45e9-4310-bb9e-4092f2574b0a

The open-access MAF lists 103 somatic variants for this specimen: 63 protein-altering or splice-affecting, 24 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 24, Intron 11, Nonsense Mutation 3, 3'UTR 2, RNA 2, Splice Site 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BIRC6 | c.2454G>T p.R818S | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.037); catalogued as COSV101427991; called by muse, mutect2, varscan2
- DNAJC7 | c.602A>T p.D201V | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV104413792; called by muse, varscan2
- FAM71B | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as rs1037471222; called by muse, mutect2
- FAT4 | c.8135G>C p.G2712A | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58696719; called by muse, mutect2
- FAT4 | c.11309G>A p.R3770Q | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as rs540725305, COSV58683662; called by muse, mutect2
- GP2 | c.684C>G p.D228E (on ENST00000381362 / NM_001007240.3; = p.D225E on NM_001502.4) | Missense Mutation (SNP) | VAF 40/316 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as rs764999700; called by muse, mutect2, varscan2
- IGFBP3 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 82/243 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs538312081, COSV51872042; called by muse, mutect2, varscan2
- ITGAM | c.2407G>C p.V803L (on ENST00000648685 / NM_001145808.2; = p.V802L on NM_000632.4) | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.127); catalogued as rs1000524164; called by muse, mutect2, varscan2
- ITIH3 | c.2498C>T p.P833L | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as COSV99819763; called by muse, mutect2, varscan2
- KIF9 | c.668A>G p.Y223C | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as rs534858181, COSV55518552; called by muse, mutect2, varscan2
- LRP2 | c.7309C>A p.Q2437K | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.244); catalogued as COSV55548982; called by muse, mutect2
- MAMDC2 | c.1217G>A p.G406E | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101015129, COSV65858391; called by muse, mutect2
- NPC1L1 | c.1546G>A p.V516I | Missense Mutation (SNP) | VAF 41/695 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.066); catalogued as rs1391033171; called by muse, mutect2
- OR56A5 | c.175C>T p.H59Y | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV60827624; called by muse, mutect2, varscan2
- OR6Y1 | c.163C>G p.H55D | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as rs1254803792; called by muse, mutect2, varscan2
- PNLIP | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 33/318 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.303); catalogued as rs1447052044, COSV65039836; called by muse, mutect2, varscan2
- RIN3 | c.2520C>A p.Y840* | Nonsense Mutation (SNP) | VAF 21/191 reads (11%) | catalogued as COSV53649448; called by muse, mutect2, varscan2
- SLITRK3 | c.2103C>G p.I701M | Missense Mutation (SNP) | VAF 26/412 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.298); catalogued as COSV53849996; called by muse, mutect2
- TMEM130 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs782725818; called by muse, mutect2, varscan2
- TNNI3 | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 26/504 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as rs730881067; ClinVar: uncertain significance; called by muse, mutect2
- TRIM3 | c.1707G>T p.K569N | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV61984725; called by muse, mutect2, varscan2
- UPK1A | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 78/582 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs551728159, COSV55878746; called by muse, mutect2, varscan2
- USP8 | c.1106A>G p.N369S | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs763497996; called by muse, mutect2, varscan2
- ZNF528 | c.-68+1G>A | Splice Site (SNP) | VAF 11/98 reads (11%) | catalogued as rs1398027779; called by muse, mutect2, varscan2
- AOC1 | c.1437G>C p.M479I | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CENPF | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- CRACR2B | c.981G>A p.M327I (on ENST00000525077 / NM_001286606.2; = p.A272T on NM_173584.4) | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.068); called by muse, mutect2
- CRACR2B | c.982C>A p.Q328K (on ENST00000525077 / NM_001286606.2; = p.A272E on NM_173584.4) | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.133); called by muse, mutect2
- CTNNBL1 | c.940T>A p.F314I | Missense Mutation (SNP) | VAF 21/299 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- CYP19A1 | c.716G>A p.W239* | Nonsense Mutation (SNP) | VAF 9/100 reads (9%) | called by muse, mutect2
- DAO | c.901T>G p.S301A | Missense Mutation (SNP) | VAF 54/362 reads (15%) | SIFT tolerated (0.91); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DVL1 | c.733A>T p.M245L | Missense Mutation (SNP) | VAF 31/316 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.354); called by muse, mutect2
- EGR4 | c.1654C>T p.R552C (on ENST00000545030; = p.R449C on NM_001965.4) | Missense Mutation (SNP) | VAF 25/447 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- EML6 | c.1856C>A p.S619Y | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FRYL | c.4265A>T p.Y1422F | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.105); called by muse, mutect2
- GLI1 | c.99A>C p.E33D | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.637); called by muse, varscan2
- GPR157 | c.460G>T p.V154L | Missense Mutation (SNP) | VAF 31/289 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IRGQ | c.1696G>T p.E566* | Nonsense Mutation (SNP) | VAF 25/166 reads (15%) | called by muse, mutect2, varscan2
- KCNMA1 | c.3591G>C p.Q1197H (on ENST00000286628 / NM_001161352.2; = p.Q1139H on NM_002247.4) | Missense Mutation (SNP) | VAF 60/644 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- KIF13B | c.3853C>T p.L1285F | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- KIF1B | c.4756C>G p.L1586V (on ENST00000377086 / NM_001365952.1; = p.L1540V on NM_015074.3) | Missense Mutation (SNP) | VAF 30/599 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.155); called by muse, mutect2
- LAMA2 | c.1411T>A p.C471S | Missense Mutation (SNP) | VAF 38/495 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- LARS1 | c.1983G>C p.E661D (on ENST00000394434 / NM_020117.11; = p.E634D on NM_016460.3) | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2
- LOXHD1 | c.2214G>T p.E738D | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.018); called by muse, mutect2
- MARF1 | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.98); called by muse, mutect2
- MGAT5 | c.1479C>A p.N493K | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- MNDA | c.206C>A p.A69D | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- MYO9A | c.1372T>G p.L458V | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, varscan2
- NFXL1 | c.1241G>A p.C414Y | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR6X1 | c.709T>C p.S237P | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PAX1 | c.1244T>C p.L415P | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); called by muse, mutect2
- POM121C | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- RRM1 | c.539A>G p.K180R | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- RRP8 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.679); called by muse, mutect2
- RTTN | c.2250G>T p.M750I | Missense Mutation (SNP) | VAF 35/211 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEC14L3 | c.589C>A p.L197M | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- SRRM2 | c.1472A>G p.K491R | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SZT2 | c.8948T>A p.L2983Q (on ENST00000634258 / NM_001365999.1; = p.L2926Q on NM_015284.4) | Missense Mutation (SNP) | VAF 29/366 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TENM3 | c.5361G>C p.K1787N | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2
- TNFRSF8 | c.142T>A p.C48S | Missense Mutation (SNP) | VAF 20/336 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- TNNI3 | c.109-1G>A p.X37_splice | Splice Site (SNP) | VAF 36/395 reads (9%) | called by muse, mutect2
- TTN | c.79468G>T p.A26490S (on ENST00000591111; = p.A19066S on NM_003319.4) | Missense Mutation (SNP) | VAF 3/41 reads (7%) | PolyPhen benign (0.292); called by muse, mutect2
- ZNF875 | c.1120A>G p.T374A | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.058); called by muse, mutect2
- CCZ1 | c.1425C>T p.F475= | Silent (SNP) | VAF 41/287 reads (14%) | called by muse, mutect2, varscan2
- CDH18 | c.2022A>T p.T674= | Silent (SNP) | VAF 51/333 reads (15%) | called by muse, mutect2, varscan2
- CDK12 | c.1743T>G p.T581= | Silent (SNP) | VAF 32/330 reads (10%) | catalogued as rs1274805953; called by muse, mutect2
- EGLN2 | c.606G>T p.L202= | Silent (SNP) | VAF 24/332 reads (7%) | called by muse, mutect2
- FAM71F1 | c.813C>T p.F271= | Silent (SNP) | VAF 20/230 reads (9%) | called by muse, mutect2
- FANCM | c.2997G>T p.P999= | Silent (SNP) | VAF 50/335 reads (15%) | called by muse, mutect2, varscan2
- FCHSD1 | c.690G>A p.L230= | Silent (SNP) | VAF 12/228 reads (5%) | catalogued as rs1246225031; called by muse, mutect2
- FNDC1 | c.5352G>A p.R1784= | Silent (SNP) | VAF 32/297 reads (11%) | called by muse, mutect2, varscan2
- GBP7 | c.276C>A p.T92= | Silent (SNP) | VAF 36/406 reads (9%) | called by muse, mutect2
- GLI1 | c.63C>T p.P21= | Silent (SNP) | VAF 46/163 reads (28%) | called by muse, varscan2
- GPR174 | c.411C>A p.I137= | Silent (SNP) | VAF 30/103 reads (29%) | called by muse, mutect2, varscan2
- ITGA11 | c.2550C>T p.N850= | Silent (SNP) | VAF 40/396 reads (10%) | catalogued as rs1244186784; called by muse, mutect2
- LINGO3 | c.1371G>T p.A457= | Silent (SNP) | VAF 20/156 reads (13%) | called by muse, mutect2, varscan2
- NOX3 | c.1305C>T p.S435= | Silent (SNP) | VAF 9/108 reads (8%) | called by muse, mutect2
- PANX1 | c.735G>A p.V245= | Silent (SNP) | VAF 35/211 reads (17%) | called by muse, mutect2, varscan2
- PCDHGA6 | c.1872C>T p.G624= | Silent (SNP) | VAF 49/473 reads (10%) | catalogued as COSV54024082; called by muse, mutect2, varscan2
- PPIL2 | c.324C>G p.T108= | Silent (SNP) | VAF 27/186 reads (15%) | catalogued as COSV58608234; called by muse, mutect2, varscan2
- RAI1 | c.2563C>T p.L855= | Silent (SNP) | VAF 42/226 reads (19%) | catalogued as rs1271175732; called by muse, mutect2, varscan2
- SERPINB3 | c.198C>G p.T66= | Silent (SNP) | VAF 31/284 reads (11%) | called by muse, mutect2
- SFI1 | c.2463G>A p.R821= (on ENST00000400288 / NM_001007467.3; = p.R790= on NM_014775.4) | Silent (SNP) | VAF 23/227 reads (10%) | catalogued as rs1209344912; called by muse, mutect2, varscan2
- STAB2 | c.7356C>T p.P2452= | Silent (SNP) | VAF 24/133 reads (18%) | catalogued as rs772653984, COSV66343051; called by muse, mutect2, varscan2
- TECTA | c.5304G>A p.A1768= | Silent (SNP) | VAF 24/240 reads (10%) | catalogued as rs373055342; ClinVar: likely benign; called by muse, mutect2
- VSTM1 | c.144G>A p.K48= | Silent (SNP) | VAF 20/274 reads (7%) | catalogued as rs768331614; called by muse, mutect2
- ZNF787 | c.261G>A p.T87= | Silent (SNP) | VAF 11/129 reads (9%) | catalogued as rs750101073, COSV99555792; called by muse, mutect2
- ABR | c.700+457G>A | Intron (SNP) | VAF 22/132 reads (17%) | called by muse, mutect2, varscan2
- AC093642.3 | n.3225C>T | RNA (SNP) | VAF 43/346 reads (12%) | called by muse, varscan2
- AKR7A2 | c.*51T>G | 3'UTR (SNP) | VAF 28/327 reads (9%) | called by muse, mutect2
- ARPP19P2 | n.249T>A | RNA (SNP) | VAF 29/227 reads (13%) | called by muse, mutect2, varscan2
- COLEC11 | c.328+969G>A | Intron (SNP) | VAF 32/446 reads (7%) | called by muse, mutect2
- D2HGDH | c.1141-106G>T | Intron (SNP) | VAF 24/164 reads (15%) | called by muse, mutect2, varscan2
- EMX1 | c.705+1025G>T | Intron (SNP) | VAF 22/183 reads (12%) | called by muse, mutect2, varscan2
- IPO5 | c.-149C>A | 5'UTR (SNP) | VAF 13/125 reads (10%) | called by muse, mutect2, varscan2
- KIF5A | c.1363-31C>G | Intron (SNP) | VAF 26/439 reads (6%) | called by muse, mutect2
- KLK12 | c.457+83C>A | Intron (SNP) | VAF 21/95 reads (22%) | called by muse, mutect2, varscan2
- LAD1 | c.*66C>A | 3'UTR (SNP) | VAF 29/404 reads (7%) | called by muse, mutect2
- MMS22L | c.607-321G>A | Intron (SNP) | VAF 10/78 reads (13%) | catalogued as rs536379694; called by muse, mutect2, varscan2
- PAX1 | c.287-33C>T | Intron (SNP) | VAF 44/280 reads (16%) | catalogued as rs185105091, COSV101270177; called by muse, mutect2, varscan2
- PTPRR | c.358-24051C>T | Intron (SNP) | VAF 28/200 reads (14%) | catalogued as COSV51739214; called by muse, mutect2, varscan2
- REG3G | c.76+9T>A | Intron (SNP) | VAF 42/236 reads (18%) | called by muse, mutect2, varscan2
- TNFRSF1B | c.458-71G>T | Intron (SNP) | VAF 51/589 reads (9%) | called by muse, mutect2
